Somatic mutation profile of tumor specimen 0E1NZS from CCDI case PBCUXD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1NZS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef409c3d-2b89-4ef4-a100-109c5e848243.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a4c2d1-456a-44cb-9956-49057e1c8615

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.8368G>A p.V2790M | Missense Mutation (SNP) | VAF 16/385 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as rs1425219391; called by muse, mutect2
- PARP10 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
